Somatic mutation profile of tumor specimen MMRF_2596_1_BM_CD138pos (aliquot MMRF_2596_1_BM_CD138pos_T1_KHS5U_L12885) from MMRF case MMRF_2596, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.2 years (26,728 days).
Specimen MMRF_2596_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf853120-70b5-4d35-81ca-65f79c402856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2596_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2596_1_PB_Whole_C3_KHS5U_L12886; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/484da648-f836-4473-9da5-719345da8402

The open-access MAF lists 102 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 18, Intron 16, Silent 11, 5'UTR 6, 5'Flank 3, Nonsense Mutation 3, Frame Shift Del 3, 3'Flank 2, Frame Shift Ins 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF19 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV54615394; called by muse, mutect2, varscan2
- BMPER | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51812574; called by muse, mutect2, varscan2
- EPHA3 | c.2764G>T p.G922C | Missense Mutation (SNP) | VAF 163/256 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1328672204, COSV60729784; called by muse, mutect2, varscan2
- FKBP1C | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as rs761723863; called by muse, mutect2, varscan2
- GNAS | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as CM002272; called by muse, mutect2, varscan2
- IGHV1-69 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 118/127 reads (93%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs191670994; called by muse, varscan2
- IGHV2-70 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 66/116 reads (57%) | catalogued as rs367964005; called by muse, varscan2
- IGLL5 | c.206+2T>A p.X69_splice | Splice Site (SNP) | VAF 19/21 reads (90%) | catalogued as rs561122720, COSV73250168, COSV73251186; called by muse, mutect2, varscan2
- IGLV4-3 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 131/141 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs746327633; called by muse, mutect2, varscan2
- IRX1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57359430; called by muse, mutect2, varscan2
- MGAM | c.4583C>T p.T1528M | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.322); catalogued as rs370790394; called by muse, mutect2, varscan2
- OR5M3 | c.265dup p.T89Nfs*31 | Frame Shift Ins (INS) | VAF 64/263 reads (24%) | catalogued as rs780048280; called by mutect2, varscan2
- PCDHGA2 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs535752252, COSV99536691; called by muse, mutect2, varscan2
- PPP1R9A | c.3286G>A p.G1096S | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1206317734; called by muse, mutect2, varscan2
- PSG11 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60458448; called by muse, mutect2, varscan2
- RTN4RL1 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.647); catalogued as rs376372113; called by muse, mutect2, varscan2
- SLC4A1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52260247; called by muse, mutect2, varscan2
- SYMPK | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.133); catalogued as rs1220858006, COSV55616407; called by muse, mutect2, varscan2
- TCF23 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1405688082; called by muse, mutect2, varscan2
- ZNF142 | c.1613A>G p.K538R (on ENST00000411696 / NM_001379660.1; = p.K338R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs528135876; called by muse, mutect2, varscan2
- ARHGEF26 | c.1923A>T p.E641D | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP10B | c.2252C>A p.P751H | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C19orf71 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- CYB561D2 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CYP4B1 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMXL2 | c.2631dup p.Q878Sfs*21 | Frame Shift Ins (INS) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- FAM171B | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM78B | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- GATA6 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); called by muse, varscan2
- HSPA13 | c.858C>A p.H286Q | Missense Mutation (SNP) | VAF 139/210 reads (66%) | SIFT tolerated (1); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- IGHV2-70 | c.155_156delinsT p.G52Vfs*4 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | called by pindel, varscan2*
- IGLV3-10 | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 135/144 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- IL33 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KCNE2 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- MAP3K14 | c.123del p.K41Nfs*18 | Frame Shift Del (DEL) | VAF 48/416 reads (12%) | called by mutect2, pindel*
- OR6X1 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OTOG | c.839G>A p.W280* | Nonsense Mutation (SNP) | VAF 105/312 reads (34%) | called by muse, mutect2, varscan2
- PKMYT1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPRJ | c.3453G>T p.E1151D | Missense Mutation (SNP) | VAF 79/303 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- RBM15B | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA6B | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- SIPA1 | c.1859_1869del p.L620Pfs*160 | Frame Shift Del (DEL) | VAF 81/143 reads (57%) | called by mutect2, pindel, varscan2
- TSC22D4 | c.929+3A>G | Splice Region (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- TTC34 | c.2951G>A p.G984D | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWDE | c.3674A>T p.N1225I | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- XKR5 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- COL4A6 | c.4176C>A p.G1392= | Silent (SNP) | VAF 65/74 reads (88%) | called by muse, mutect2, varscan2
- COMTD1 | c.205C>T p.L69= | Silent (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- DHX36 | c.3026G>A p.*1009= | Silent (SNP) | VAF 160/549 reads (29%) | called by muse, mutect2, varscan2
- DPP6 | c.1392G>A p.T464= (on ENST00000377770 / NM_001364500.2; = p.T402= on NM_001936.5) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs759587439, COSV59629369; called by muse, mutect2, varscan2
- FN1 | c.945C>T p.V315= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as COSV60558533; called by muse, mutect2, varscan2
- GLT8D1 | c.270C>T p.N90= | Silent (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- IFNL3 | c.249G>A p.R83= | Silent (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- MBP | c.234G>A p.Q78= | Silent (SNP) | VAF 183/400 reads (46%) | called by muse, mutect2, varscan2
- TIMMDC1 | c.555G>C p.L185= | Silent (SNP) | VAF 79/273 reads (29%) | called by muse, mutect2, varscan2
- TINAG | c.1335T>C p.N445= | Silent (SNP) | VAF 131/305 reads (43%) | catalogued as rs769592996; called by muse, mutect2
- ZSWIM6 | c.606G>A p.E202= | Silent (SNP) | VAF 54/83 reads (65%) | called by muse, mutect2, varscan2
- ACTRT3 | c.*105T>C | 3'UTR (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2, varscan2
- AL162231.1 | c.108-23G>C | Intron (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.*1476G>A | 3'UTR (SNP) | VAF 112/237 reads (47%) | catalogued as rs1431824990; called by muse, mutect2, varscan2
- ASPRV1 | c.*63del | 3'UTR (DEL) | VAF 74/172 reads (43%) | catalogued as rs557018270; called by mutect2, varscan2
- BARHL2 | c.-53C>T | 5'UTR (SNP) | VAF 111/269 reads (41%) | called by muse, mutect2, varscan2
- CD36 | c.1255-39A>G | Intron (SNP) | VAF 29/111 reads (26%) | catalogued as rs1323122280; called by muse, mutect2, varscan2
- CRELD1 | c.-580A>G | 5'UTR (SNP) | VAF 53/241 reads (22%) | catalogued as rs1033567471; called by muse, mutect2, varscan2
- CSTA | c.168+390C>T | Intron (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- DCAF5 | c.*1748G>A | 3'UTR (SNP) | VAF 100/459 reads (22%) | called by muse, mutect2, varscan2
- DNAJC21 | c.*2376C>T | 3'UTR (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- FAM86C1P | n.434+89A>T | Intron (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- GRAMD4 | c.*1667A>G | 3'UTR (SNP) | VAF 121/147 reads (82%) | called by muse, mutect2, varscan2
- HEBP1 | chr12:13001664 G>T | 5'Flank (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- HEG1 | c.*3451A>T | 3'UTR (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- IL1R1 | c.*1922A>G | 3'UTR (SNP) | VAF 45/96 reads (47%) | catalogued as rs1055954566; called by muse, mutect2, varscan2
- KLHL3 | c.241+2152A>T | Intron (SNP) | VAF 69/207 reads (33%) | called by muse, mutect2, varscan2
- LAMB2 | c.1890+35C>A | Intron (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- MECOM | chr3:169084354 G>A | 3'Flank (SNP) | VAF 38/111 reads (34%) | catalogued as rs1371724908; called by muse, mutect2, varscan2
- MSRB2 | c.297-95C>T | Intron (SNP) | VAF 18/47 reads (38%) | catalogued as rs939810735; called by muse, mutect2, varscan2
- NEXMIF | c.*5485T>G | 3'UTR (SNP) | VAF 29/36 reads (81%) | called by muse, mutect2, varscan2
- ODF3B | c.-18G>A | 5'UTR (SNP) | VAF 13/15 reads (87%) | called by mutect2, varscan2
- PCDH15 | c.*470T>A | 3'UTR (SNP) | VAF 66/144 reads (46%) | catalogued as COSV64737441; called by muse, mutect2, varscan2
- PMEL | c.-52+244A>T | Intron (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- PNP | c.-70C>T | 5'UTR (SNP) | VAF 45/94 reads (48%) | catalogued as rs1319429930; called by muse, mutect2, varscan2
- POU2AF1 | c.-58C>A | 5'UTR (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- PPP2R5D | c.*1033C>T | 3'UTR (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
- PTPRK | chr6:127969567 G>T | 3'Flank (SNP) | VAF 62/133 reads (47%) | called by muse, mutect2, varscan2
- RBPMS | c.-281C>T | 5'UTR (SNP) | VAF 38/96 reads (40%) | catalogued as rs948040959; called by muse, mutect2, varscan2
- RCE1 | c.754+124C>A | Intron (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- RNPS1 | chr16:2268252 G>T | 5'Flank (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.174+13255A>C | Intron (SNP) | VAF 100/245 reads (41%) | called by muse, mutect2, varscan2
- SATB2 | c.347-15938C>T | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs373895353; called by muse, varscan2
- SERPINA3 | c.644-1387dup | Intron (INS) | VAF 28/54 reads (52%) | catalogued as rs1566847168; called by mutect2, varscan2
- SLC17A6 | c.*1201T>C | 3'UTR (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- SLC25A30 | c.*361A>C | 3'UTR (SNP) | VAF 20/24 reads (83%) | called by muse, mutect2, varscan2
- SPRY4 | c.*1273G>C | 3'UTR (SNP) | VAF 29/232 reads (13%) | called by muse, mutect2, varscan2
- SSBP2 | c.*4163C>T | 3'UTR (SNP) | VAF 41/149 reads (28%) | called by muse, mutect2, varscan2
- TMEM108 | c.1451-2449G>A | Intron (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- TMEM132D | c.*872T>G | 3'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- TRMT1 | c.311-35G>A | Intron (SNP) | VAF 104/319 reads (33%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1088_*1108del | 3'UTR (DEL) | VAF 15/198 reads (8%) | called by mutect2, pindel
- UGT3A1 | chr5:35991449 C>A | 5'Flank (SNP) | VAF 81/133 reads (61%) | called by muse, mutect2, varscan2
- USP31 | c.*5664_*5666del | 3'UTR (DEL) | VAF 5/38 reads (13%) | called by pindel, varscan2
- VWA3B | c.2674-4794A>G | Intron (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- XG | c.127+87C>T | Intron (SNP) | VAF 90/101 reads (89%) | called by muse, mutect2, varscan2
